Somatic mutation profile of tumor specimen TCGA-BG-A0VZ-01A (aliquot TCGA-BG-A0VZ-01A-11D-A10G-09) from TCGA case TCGA-BG-A0VZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 58.6 years (21,414 days).
Specimen TCGA-BG-A0VZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb9d3430-0db6-4677-9c65-1923730e8650.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0VZ-10A (Blood Derived Normal), aliquot TCGA-BG-A0VZ-10A-02D-A117-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b480736e-e959-441a-bf04-60b976a9d29d

The open-access MAF lists 409 somatic variants for this specimen: 305 protein-altering or splice-affecting, 98 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 187, Silent 98, Frame Shift Del 73, Frame Shift Ins 18, Nonsense Mutation 17, Splice Site 5, RNA 4, Splice Region 3, Translation Start Site 1, In Frame Del 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 63/140 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- LAMA2 | c.5290del p.E1764Kfs*27 | Frame Shift Del (DEL) | VAF 26/75 reads (35%) | catalogued as rs1415944134, COSV101370451, COSV70355297; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MAPT | c.2392C>T p.R798W (on ENST00000262410 / NM_001377265.1; = p.R406W on NM_005910.5) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs63750424, CM981237, COSV52241933; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 76/220 reads (35%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 12/23 reads (52%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55876538, COSV55894288; called by muse, mutect2, varscan2
- PIK3CA | c.3132T>G p.N1044K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen possibly damaging (0.63); catalogued as COSV55875087, COSV55897116; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 104/138 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- ACP3 | c.556-1G>T p.X186_splice | Splice Site (SNP) | VAF 93/265 reads (35%) | catalogued as COSV60486995; called by muse, mutect2, varscan2
- ACTA1 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as CM095302, CM095303, COSV64203373; called by muse, mutect2, varscan2
- ACTRT1 | c.510G>T p.E170D | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV64419623; called by muse, mutect2, varscan2
- ADGRG4 | c.3320C>T p.T1107I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.403); catalogued as COSV54959518; called by muse, mutect2, varscan2
- ADRA1B | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs559921269, COSV60702524; called by muse, mutect2, varscan2
- AFF3 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV57858127; called by muse, mutect2, varscan2
- ALDH1B1 | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as rs202177927, COSV66620111, COSV99081196; called by muse, mutect2, varscan2
- ALDH8A1 | c.653T>C p.L218P | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55642524; called by muse, mutect2, varscan2
- ALG13 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); catalogued as COSV52640663; called by muse, mutect2, varscan2
- ANAPC2 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772824308, COSV60570646; called by muse, mutect2, varscan2
- ANK1 | c.3193A>G p.I1065V | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1318626902, COSV55884902; called by muse, mutect2, varscan2
- ANK3 | c.9256G>A p.G3086R | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.11); catalogued as COSV55064291, COSV99781889; called by muse, mutect2, varscan2
- APOB | c.13399G>T p.A4467S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.423); catalogued as COSV51940459; called by muse, mutect2
- ARPIN | c.402del p.D135Tfs*15 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | catalogued as COSV62590253; called by mutect2, varscan2
- ASPH | c.1446T>G p.S482R | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV65245288; called by muse, mutect2, varscan2
- ATAD3A | c.269A>G p.Q90R | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs147308420; called by muse, mutect2, varscan2
- ATF7IP | c.3665T>G p.L1222R | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53772772; called by muse, mutect2, varscan2
- ATP10A | c.2831A>G p.E944G | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV63519160; called by muse, mutect2
- ATP2B4 | c.261dup p.K88Qfs*40 | Frame Shift Ins (INS) | VAF 32/94 reads (34%) | catalogued as rs769726180; called by mutect2, varscan2
- AXIN2 | c.2273C>T p.A758V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs777885192, COSV61056181; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GNT4 | c.214C>A p.R72S | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV57336727, COSV99927964; called by muse, mutect2
- BBX | c.1921C>T p.R641* | Nonsense Mutation (SNP) | VAF 46/107 reads (43%) | catalogued as COSV57879776; called by muse, mutect2, varscan2
- BEND5 | c.1052del p.K351Rfs*15 | Frame Shift Del (DEL) | VAF 46/152 reads (30%) | catalogued as rs756345162, COSV65718189; called by mutect2, varscan2
- BMS1 | c.2815C>T p.R939* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV65733748; called by muse, mutect2, varscan2
- BOD1 | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 95/240 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs758005393, COSV53632766; called by muse, mutect2, varscan2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | catalogued as COSV56263190; called by mutect2, pindel, varscan2
- BRD1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53458523, COSV53462855; called by muse, mutect2, varscan2
- BRIP1 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 88/286 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV52001689; called by muse, mutect2, varscan2
- BRSK2 | c.1063dup p.R355Pfs*48 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs779380593; called by mutect2, varscan2
- C20orf141 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.077); catalogued as COSV63028290; called by muse, mutect2, varscan2
- CACNA1D | c.5840C>T p.T1947M (on ENST00000350061 / NM_001128840.3; = p.T1967M on NM_000720.4) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs752102016, COSV55452349; called by muse, mutect2, varscan2
- CARMIL3 | c.531G>T p.W177C | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57727020; called by muse, mutect2, varscan2
- CATSPERG | c.2716T>G p.Y906D | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53049867; called by muse, mutect2, varscan2
- CDC16 | c.1376+3_1376+6del p.X459_splice | Splice Site (DEL) | VAF 51/157 reads (32%) | catalogued as rs759504424; called by pindel, varscan2
- CDC5L | c.2249G>A p.R750H | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs202064406, COSV65175259; called by muse, mutect2, varscan2
- CDC73 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as CM045278, COSV66467849; called by muse, mutect2, varscan2
- CDH10 | c.280T>C p.S94P | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52568561; called by muse, mutect2, varscan2
- CDH19 | c.1664A>G p.N555S | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.99); catalogued as rs1221560248, COSV50963056; called by muse, mutect2
- CEL | c.506G>C p.G169A (on ENST00000673714; = p.G166A on NM_001807.6) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV60828115; called by muse, mutect2, varscan2
- CEP290 | c.7153del p.I2385* | Frame Shift Del (DEL) | VAF 77/246 reads (31%) | catalogued as rs781310385; called by mutect2, pindel, varscan2
- CFAP61 | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as rs770472220, COSV55634268; called by muse, mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 100/289 reads (35%) | catalogued as rs1561489348; called by mutect2, pindel, varscan2
- CHD9 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 101/211 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as rs181647712, COSV54610812; called by muse, mutect2, varscan2
- CHL1 | c.1886G>A p.R629Q (on ENST00000397491 / NM_001253387.1; = p.R645Q on NM_006614.4) | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs1273690025, COSV56596424; called by muse, mutect2, varscan2
- CIC | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.078); catalogued as rs771399534, COSV50599743; called by muse, mutect2, varscan2
- CLDN16 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1444245867, CM085326, COSV53228283; called by muse, mutect2, varscan2
- CNTN2 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 4/68 reads (6%) | catalogued as COSV59350893; called by muse, mutect2
- COPS4 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52315726; called by muse, mutect2
- CPD | c.2373G>A p.Q791= | Splice Region (SNP) | VAF 8/90 reads (9%) | catalogued as COSV56713841; called by muse, mutect2
- CRYGB | c.426del p.R143Gfs*5 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as COSV53679706; called by mutect2, pindel, varscan2
- CSMD2 | c.9560-1G>A p.X3187_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as COSV53924629; called by muse, mutect2, varscan2
- CSRNP2 | c.708+2T>G p.X236_splice | Splice Site (SNP) | VAF 22/63 reads (35%) | catalogued as COSV57334553; called by muse, mutect2, varscan2
- CUL2 | c.2089A>T p.N697Y | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66079543; called by muse, mutect2, varscan2
- CUL7 | c.1660A>G p.S554G | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV54818682; called by muse, mutect2, varscan2
- CYP2F1 | c.1174C>A p.L392I | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV58527958; called by muse, mutect2, varscan2
- DCAF12L2 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776609885, COSV100758723, COSV63580588; called by muse, mutect2, varscan2
- DCHS1 | c.7810C>T p.R2604* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV54998379; called by muse, mutect2, varscan2
- DIRAS3 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs776654083, COSV63970756, COSV63970862; called by muse, mutect2, varscan2
- DMD | c.7712G>A p.R2571Q | Missense Mutation (SNP) | VAF 123/361 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371588290, COSV58921022; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DOP1B | c.2541del p.F847Lfs*7 | Frame Shift Del (DEL) | VAF 43/154 reads (28%) | catalogued as rs750520568; called by mutect2, pindel, varscan2
- DPP4 | c.1753T>C p.Y585H | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62107638; called by muse, mutect2, varscan2
- DPP6 | c.1418G>A p.S473N (on ENST00000377770 / NM_001364500.2; = p.S411N on NM_001936.5) | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.666); catalogued as COSV59599070; called by muse, mutect2, varscan2
- DSCAML1 | c.4153A>G p.K1385E (on ENST00000321322; = p.K1325E on NM_020693.4) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58394492; called by muse, mutect2
- EGFR | c.2005C>T p.R669* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as rs1231769201, COSV51812193; called by muse, mutect2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 99/242 reads (41%) | catalogued as rs748937918; called by mutect2, varscan2
- ENPP3 | c.716T>A p.L239H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62954817; called by muse, mutect2, varscan2
- ERLIN1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as rs900216990, COSV64941236; called by muse, mutect2, varscan2
- ESD | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 52/162 reads (32%) | catalogued as COSV66340481; called by muse, mutect2, varscan2
- ESR2 | c.1054G>T p.G352C | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50833438; called by muse, mutect2, varscan2
- EVA1A | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as rs761924250, COSV52059603; called by muse, mutect2, varscan2
- FAM168A | c.268G>A p.E90K (on ENST00000064778 / NM_001286050.2; = p.E81K on NM_015159.3) | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated, low confidence (0.4); PolyPhen probably damaging (0.956); catalogued as COSV50358424; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 158/402 reads (39%) | catalogued as rs748967872; called by mutect2, varscan2
- FAN1 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs1262731851, COSV62951065; called by muse, mutect2, varscan2
- FBXO39 | c.734G>A p.C245Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.365); catalogued as rs369101262; called by muse, mutect2, varscan2
- FBXW11 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV51610483; called by muse, mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 48/141 reads (34%) | catalogued as rs752076602; called by mutect2, pindel, varscan2
- FSTL5 | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV60202727; called by muse, mutect2, varscan2
- GDF2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1555208722; called by muse, mutect2, varscan2
- GLCCI1 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs985423353; called by muse, mutect2
- GPR158 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371864751; called by muse, mutect2, varscan2
- GPR84 | c.82del p.V28Wfs*5 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | catalogued as rs759103894; called by mutect2, pindel, varscan2
- GPRASP1 | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as COSV64355902; called by muse, mutect2, varscan2
- H1-2 | c.64A>C p.K22Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59191183; called by muse, mutect2
- HDAC6 | c.2162G>A p.R721H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.227); catalogued as COSV61929472; called by muse, mutect2, varscan2
- HIVEP1 | c.4657G>A p.E1553K | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.024); catalogued as COSV65102728; called by muse, mutect2, varscan2
- HIVEP3 | c.1974C>G p.Y658* | Nonsense Mutation (SNP) | VAF 43/104 reads (41%) | catalogued as COSV56011524, COSV56017428; called by muse, mutect2, varscan2
- HLA-F | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.48); catalogued as COSV52576171, COSV99465608; called by muse, mutect2, varscan2
- HMGCR | c.836_838del p.P279del | In Frame Del (DEL) | VAF 54/160 reads (34%) | catalogued as rs554100316; called by pindel, varscan2
- HPDL | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV58344409; called by muse, mutect2, varscan2
- HS2ST1 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as rs867578348, COSV63351105; called by muse, mutect2, varscan2
- HSPA4 | c.2398G>A p.A800T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59182741; called by muse, mutect2, varscan2
- IDH2 | c.804G>T p.E268D | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV57476026; called by muse, mutect2, varscan2
- IFRD1 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV50044398; called by muse, mutect2, varscan2
- IGF1R | c.2488G>T p.G830* | Nonsense Mutation (SNP) | VAF 25/72 reads (35%) | catalogued as COSV51303764; called by muse, mutect2, varscan2
- IGSF9 | c.1922T>C p.L641P (on ENST00000368094 / NM_001135050.2; = p.L625P on NM_020789.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63640606; called by muse, mutect2, varscan2
- IL1R1 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52106606; called by muse, mutect2, varscan2
- IL2RB | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as rs867008739, COSV53426968; called by muse, mutect2, varscan2
- INPP4A | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs774761280, COSV50798464; called by muse, mutect2, varscan2
- KCNK9 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs765898630, COSV57279529; called by muse, mutect2, varscan2
- KEL | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.315); catalogued as COSV62335825; called by muse, mutect2, varscan2
- KLC4 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs562531990, COSV52436676; called by muse, mutect2, varscan2
- KMT2B | c.3602del p.P1201Rfs*154 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | catalogued as COSV55870773; called by mutect2, varscan2
- LGR6 | c.467G>A p.R156K (on ENST00000367278 / NM_001017403.1; = p.R104K on NM_021636.3) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.021); catalogued as COSV55159633; called by muse, mutect2, varscan2
- LRP2 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs138667752; called by muse, mutect2, varscan2
- LRRC37B | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs778010939, COSV58952969; called by muse, mutect2, varscan2
- LY75 | c.1588C>G p.L530V | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55107854; called by muse, mutect2, varscan2
- MAGEC1 | c.780del p.F260Lfs*13 | Frame Shift Del (DEL) | VAF 36/110 reads (33%) | catalogued as rs1569477532, COSV53582527, COSV99594727; called by pindel, varscan2
- MAGEC3 | c.1066del p.Q356Rfs*8 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as COSV100026088, COSV68923837; called by mutect2, pindel, varscan2
- MANBA | c.2338C>T p.R780C (on ENST00000642252; = p.R734C on NM_005908.4) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs750688426, COSV56963858; called by muse, mutect2, varscan2
- MAP2K3 | c.625T>G p.F209V (on ENST00000342679 / NM_145109.3; = p.F180V on NM_002756.4) | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57570113; called by muse, mutect2, varscan2
- MBD6 | c.2965C>T p.R989C | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs138744350; called by muse, mutect2, varscan2
- MCC | c.1957C>T p.R653W | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as rs139015770; called by muse, mutect2, varscan2
- MCM2 | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757718055, COSV54034578; called by muse, mutect2, varscan2
- MCRS1 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs967931087, COSV57789258; called by muse, mutect2, varscan2
- MKNK1 | c.1028T>C p.L343P | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57861705; called by muse, mutect2, varscan2
- MNDA | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs559502950, COSV63740322; called by muse, mutect2, varscan2
- MOCOS | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776357546, COSV54341525; ClinVar: uncertain significance; called by muse, mutect2
- MOK | c.313del p.I105Lfs*25 | Frame Shift Del (DEL) | VAF 19/84 reads (23%) | catalogued as rs753079987; called by mutect2, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 17/48 reads (35%) | catalogued as rs777649506, COSV53202254; called by mutect2, pindel, varscan2
- MORC4 | c.2560C>T p.Q854* | Nonsense Mutation (SNP) | VAF 108/337 reads (32%) | catalogued as COSV55243586; called by muse, mutect2, varscan2
- MPPED1 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); catalogued as rs749639689, COSV68837441; called by muse, mutect2, varscan2
- MTF1 | c.2120C>A p.P707H | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as COSV65989594; called by muse, mutect2
- MXD4 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs772082970, COSV61466455; called by muse, mutect2, varscan2
- MYCBP2 | c.9539G>A p.R3180K (on ENST00000357337; = p.R3218K on NM_015057.5) | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.344); catalogued as rs1158777274, COSV62025154; called by muse, mutect2, varscan2
- MYO5B | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs754668788, COSV53222008; called by muse, mutect2, varscan2
- MYO9A | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs755901127, COSV61852994; called by muse, mutect2, varscan2
- MYOM3 | c.3055C>T p.R1019* | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | catalogued as rs183674235, COSV58395661; called by muse, mutect2, varscan2
- MYORG | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52627544; called by muse, mutect2
- NBEA | c.7811C>T p.A2604V | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV59795410, COSV59811249; called by muse, mutect2, varscan2
- NCF2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs768181039, COSV62315817; called by muse, mutect2, varscan2
- NDUFA2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV52800095; called by muse, mutect2, varscan2
- NDUFAF1 | c.737del p.G246Dfs*37 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | catalogued as COSV52975801; called by mutect2, pindel, varscan2
- NFIA | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63608914; called by muse, mutect2, varscan2
- NISCH | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV61900764; called by muse, mutect2, varscan2
- NKAPD1 | c.504dup p.Q169Tfs*18 (on ENST00000280352 / NM_001082970.2; = p.Q170Tfs*18 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 58/179 reads (32%) | catalogued as rs757462125; called by mutect2, pindel, varscan2
- NKTR | c.427G>T p.V143F | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV51772944; called by muse, mutect2, varscan2
- NRK | c.2429G>A p.R810Q | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs962537829, COSV54599369; called by muse, mutect2
- NUDT8 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as rs745587907, COSV56875844; called by muse, mutect2, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 110/292 reads (38%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- NUP214 | c.3312G>T p.Q1104H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63910574; called by muse, mutect2, varscan2
- OR14C36 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58601760; called by muse, mutect2
- OR5F1 | c.606G>C p.L202F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53547110, COSV53547870; called by muse, mutect2, varscan2
- OR5L2 | c.388del p.L130Cfs*5 | Frame Shift Del (DEL) | VAF 37/124 reads (30%) | catalogued as COSV99058732; called by mutect2, pindel, varscan2
- OR5T1 | c.602G>T p.C201F | Missense Mutation (SNP) | VAF 87/228 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs773014367, COSV57303326; called by muse, mutect2, varscan2
- OR9A4 | c.527A>T p.N176I | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV71885623; called by muse, mutect2
- PAFAH1B2 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs745995174, COSV59166989; called by muse, mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 31/74 reads (42%) | catalogued as rs753190856; called by mutect2, varscan2
- PCDH11X | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53476808; called by muse, mutect2, varscan2
- PCDHA10 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as COSV56515687; called by muse, mutect2, varscan2
- PCGF5 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs764871600, COSV60238299; called by muse, mutect2, varscan2
- PDZD4 | c.1203G>A p.M401I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV51247729; called by muse, mutect2, varscan2
- PHACTR2 | c.685del p.T229Qfs*47 | Frame Shift Del (DEL) | VAF 24/79 reads (30%) | catalogued as rs746858891; called by mutect2, varscan2
- PKMYT1 | c.1012A>G p.M338V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs772244440, COSV51891760; called by muse, mutect2
- PLEKHH1 | c.3999del p.T1334Pfs*43 | Frame Shift Del (DEL) | VAF 72/185 reads (39%) | catalogued as rs761759640; called by mutect2, pindel, varscan2
- POM121 | c.932C>T p.T311I (on ENST00000434423; = p.T46I on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 182/417 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57517933; called by muse, mutect2, varscan2
- POT1 | c.1346A>G p.N449S | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV62931443; called by muse, mutect2, varscan2
- PPEF1 | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV62996009; called by muse, mutect2, varscan2
- PRDM2 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1169511958, COSV52449435, COSV52453446; called by muse, mutect2, varscan2
- PRKCI | c.826dup p.T276Nfs*16 | Frame Shift Ins (INS) | VAF 50/148 reads (34%) | catalogued as rs753143066; called by mutect2, varscan2
- PRTG | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV66838671; called by muse, mutect2, varscan2
- PSG8 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); catalogued as COSV60612880, COSV60614275; called by muse, mutect2
- PSMB11 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs559769324, COSV57461888; called by muse, mutect2, varscan2
- PSMC3IP | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV53816181; called by muse, mutect2, varscan2
- PTCHD1 | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as rs769407241, CM109473, COSV65061317; called by muse, mutect2, varscan2
- PTPN3 | c.1414G>T p.G472C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as rs750357031, COSV52704835, COSV52707251; called by muse, mutect2, varscan2
- PTPRB | c.911C>T p.T304I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs755358741, COSV54244300; called by muse, mutect2, varscan2
- PWWP3B | c.1068C>A p.D356E | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as COSV61800236; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1303T>A p.Y435N | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV51934699; called by muse, mutect2, varscan2
- RAB1B | c.241del p.A81Lfs*19 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as COSV57581555; called by mutect2, pindel, varscan2
- RAET1L | c.196T>C p.C66R | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53953461; called by muse, mutect2, varscan2
- RAPGEF1 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 66/149 reads (44%) | catalogued as COSV64699620, COSV64700242; called by muse, mutect2, varscan2
- RASSF2 | c.324G>T p.Q108H | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV65082107, COSV65082391; called by muse, mutect2, varscan2
- RB1 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as CD952453, COSV57298288, COSV57312557; called by muse, mutect2, varscan2
- RBFOX2 | c.745C>T p.R249C (on ENST00000438146 / NM_001349995.2; = p.R179C on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53265601; called by muse, mutect2, varscan2
- RBM22 | c.1015C>G p.P339A | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV52272220; called by muse, mutect2
- RCOR1 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV51769173; called by muse, mutect2, varscan2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 33/76 reads (43%) | catalogued as rs753959887; called by mutect2, varscan2
- RIOX2 | c.1022del p.P341Lfs*23 (on ENST00000333396 / NM_001042533.2; = p.P340Lfs*23 on NM_032778.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | catalogued as COSV51714857; called by mutect2, pindel, varscan2
- RNF19B | c.1872A>C p.E624D | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.073); catalogued as COSV52388304; called by muse, mutect2, varscan2
- SAMD12 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV59051709; called by muse, mutect2, varscan2
- SAP130 | c.2999A>G p.Q1000R | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as COSV52098800; called by muse, mutect2, varscan2
- SAPCD2 | c.685C>T p.L229= | Splice Region (SNP) | VAF 18/33 reads (55%) | catalogued as COSV68836574; called by muse, mutect2, varscan2
- SBNO2 | c.2774A>C p.Q925P | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.663); catalogued as rs1185047873, COSV62321389; called by muse, mutect2, varscan2
- SEL1L3 | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.738); catalogued as rs779340509, COSV53543530; called by muse, mutect2, varscan2
- SEPTIN11 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV53582443; called by muse, mutect2, varscan2
- SETDB1 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 62/145 reads (43%) | catalogued as COSV54984819, COSV54985798; called by muse, mutect2, varscan2
- SEZ6 | c.1237A>G p.I413V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV57981756; called by muse, mutect2, varscan2
- SFRP4 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.28); catalogued as rs140561432, COSV71412308; called by muse, mutect2, varscan2
- SIPA1L1 | c.172del p.R58Efs*8 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs1567251966; called by mutect2, pindel
- SLC25A5 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV58627130; called by muse, mutect2, varscan2
- SLC35G6 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs772915658, COSV59493287; called by muse, varscan2
- SLC6A9 | c.350C>A p.A117D (on ENST00000360584 / NM_201649.4; = p.A63D on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62211097; called by muse, mutect2, varscan2
- SLX4 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV53565249; called by muse, mutect2, varscan2
- SMAP1 | c.613del p.S205Vfs*15 (on ENST00000370455 / NM_001044305.3; = p.S178Vfs*15 on NM_021940.5) | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | catalogued as rs766085867, COSV100391091; called by mutect2, pindel, varscan2
- SNTN | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.904); catalogued as COSV59539099; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 62/167 reads (37%) | catalogued as rs768873484; called by mutect2, varscan2
- SNX6 | c.1118-2A>G p.X373_splice (on ENST00000652385; = p.X245_splice on NM_021249.5) | Splice Site (SNP) | VAF 84/209 reads (40%) | catalogued as COSV61919045; called by muse, mutect2, varscan2
- SON | c.4136C>T p.S1379L | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs906057051, COSV51650647; called by muse, mutect2, varscan2
- SPDYC | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as rs370497227, COSV65865338; called by muse, mutect2, varscan2
- SPTBN1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61689739; called by muse, mutect2, varscan2
- SSX3 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 139/416 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.183); catalogued as COSV53644518; called by muse, mutect2, varscan2
- ST8SIA1 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs769664548, COSV53955420; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 42/116 reads (36%) | catalogued as rs752994755; called by mutect2, varscan2
- STARD6 | c.352A>G p.K118E | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV57142675; called by muse, mutect2, varscan2
- SUGP2 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV58260761; called by muse, mutect2, varscan2
- SULF1 | c.223del p.A75Pfs*8 | Frame Shift Del (DEL) | VAF 38/109 reads (35%) | catalogued as rs747316268, COSV52690552; called by mutect2, pindel, varscan2
- SUSD5 | c.672G>T p.M224I | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV58878495; called by muse, mutect2, varscan2
- TAPBP | c.763A>T p.T255S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.678); catalogued as COSV70457260; called by muse, mutect2, varscan2
- TBC1D16 | c.1244A>G p.Y415C | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as COSV60478720; called by muse, mutect2, varscan2
- TDRD7 | c.1507A>G p.S503G | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV62428585, COSV62429949; called by muse, mutect2, varscan2
- TENM2 | c.6625G>T p.G2209W (on ENST00000518659 / NM_001122679.2; = p.G1970W on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756812300, COSV69133581; called by muse, mutect2
- TENM3 | c.3809C>T p.A1270V | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs1208530808, COSV69311377; called by muse, mutect2, varscan2
- TICRR | c.5476G>T p.G1826C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51542741; called by mutect2, varscan2
- TMCO3 | c.990dup p.T331Yfs*76 | Frame Shift Ins (INS) | VAF 109/532 reads (20%) | catalogued as rs756357693; called by pindel, varscan2
- TMEM178A | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV56142389; called by muse, mutect2, varscan2
- TRAM1 | c.965G>T p.R322M | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV51598794, COSV99140710; called by muse, mutect2, varscan2
- TRAPPC9 | c.3437C>T p.A1146V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as rs754061906, COSV66902322; called by muse, mutect2, varscan2
- TRIM60 | c.969dup p.R324Tfs*6 | Frame Shift Ins (INS) | VAF 32/90 reads (36%) | catalogued as rs745660493; called by mutect2, varscan2
- TRPM6 | c.3520C>T p.R1174* | Nonsense Mutation (SNP) | VAF 57/178 reads (32%) | catalogued as COSV62503093; called by muse, mutect2, varscan2
- TSEN2 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs186223564, COSV53189466, COSV53190565; called by muse, mutect2, varscan2
- TSPAN12 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs905693826, COSV56080319; called by muse, mutect2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 28/88 reads (32%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.38453G>A p.G12818D (on ENST00000591111; = p.G5394D on NM_003319.4) | Missense Mutation (SNP) | VAF 73/167 reads (44%) | PolyPhen probably damaging (1); catalogued as COSV60146232; called by muse, mutect2, varscan2
- UBA7 | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs545334951, COSV60967862; called by muse, mutect2, varscan2
- UBE2R2 | c.253A>G p.N85D | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54290417; called by muse, mutect2, varscan2
- UGT2B17 | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1471569928, COSV100497153; called by muse, mutect2
- UNC13D | c.2444G>A p.S815N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52885419; called by muse, varscan2
- UNC45A | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs549730654, COSV57746211; called by muse, mutect2, varscan2
- UPF2 | c.2126C>A p.T709K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV62661553; called by muse, mutect2, varscan2
- USP48 | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 107/255 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57608314, COSV57614578; called by muse, mutect2, varscan2
- VOPP1 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53388076, COSV53391115; called by muse, mutect2, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 36/108 reads (33%) | catalogued as rs1557951659, COSV63058584; called by mutect2, pindel, varscan2
- WNK1 | c.7124del p.P2375Qfs*15 (on ENST00000315939 / NM_018979.4; = p.P2127Qfs*15 on NM_014823.3) | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs1565626263; called by mutect2, pindel, varscan2
- WNT5B | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60198259; called by muse, mutect2, varscan2
- XIRP2 | c.2131G>T p.A711S (on ENST00000628543; = p.A886S on NM_152381.6) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.122); catalogued as COSV54710017; called by muse, mutect2, varscan2
- XIRP2 | c.4949A>G p.Q1650R (on ENST00000628543; = p.Q1825R on NM_152381.6) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.255); catalogued as rs754562833, COSV54710031; called by muse, mutect2, varscan2
- XPO4 | c.1912A>G p.I638V | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.168); catalogued as COSV55009118; called by muse, mutect2
- ZBTB4 | c.11del p.P4Lfs*4 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs765991494; called by mutect2, varscan2
- ZBTB7B | c.1164G>T p.K388N (on ENST00000292176; = p.K422N on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52692111, COSV52692260; called by muse, mutect2, varscan2
- ZFHX3 | c.5512C>T p.Q1838* | Nonsense Mutation (SNP) | VAF 34/68 reads (50%) | catalogued as COSV51723106; called by muse, mutect2, varscan2
- ZNF331 | c.182dup p.N61Kfs*4 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | catalogued as rs1476112027; called by mutect2, varscan2
- ZNF366 | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.995); catalogued as COSV59216509; called by muse, mutect2, varscan2
- ZNF536 | c.1970G>T p.R657L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs556954524, COSV62824617, COSV62826657; called by muse, mutect2, varscan2
- ZNF548 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV60241238; called by muse, mutect2, varscan2
- ZNF563 | c.764G>A p.C255Y | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53371005; called by muse, mutect2, varscan2
- ZNF684 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV65519252; called by muse, mutect2, varscan2
- ZNF875 | c.1412G>A p.C471Y | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60992255; called by muse, mutect2, varscan2
- ACAN | c.7466del p.P2489Lfs*120 (on ENST00000560601 / NM_001369268.1; = p.P2451Lfs*120 on NM_013227.3) | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | called by mutect2, varscan2
- ACBD4 | c.629del p.P210Hfs*49 (on ENST00000376955 / NM_001378111.1; = p.T214Qfs*116 on NM_024722.4) | Frame Shift Del (DEL) | VAF 32/93 reads (34%) | called by mutect2, pindel, varscan2
- ADAL | c.651del p.E218Kfs*33 | Frame Shift Del (DEL) | VAF 13/85 reads (15%) | called by mutect2, varscan2
- AGGF1 | c.2042del p.N681Tfs*29 | Frame Shift Del (DEL) | VAF 29/85 reads (34%) | called by mutect2, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | called by mutect2, pindel, varscan2
- ASMTL | c.1826del p.G609Vfs*22 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | called by mutect2, pindel, varscan2
- ATRNL1 | c.2775del p.P926Hfs*6 | Frame Shift Del (DEL) | VAF 48/162 reads (30%) | called by mutect2, pindel, varscan2
- C1R | c.689del p.P230Lfs*100 (on ENST00000536053 / NM_001354346.2; = p.P216Lfs*100 on NM_001733.7) | Frame Shift Del (DEL) | VAF 34/99 reads (34%) | called by mutect2, pindel, varscan2
- CCL16 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 94/243 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CCR4 | c.315del p.F105Lfs*3 | Frame Shift Del (DEL) | VAF 129/394 reads (33%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- CLDN16 | c.570del p.F190Lfs*14 | Frame Shift Del (DEL) | VAF 76/207 reads (37%) | called by mutect2, pindel, varscan2
- CMTM4 | c.628dup p.S210Ffs*31 | Frame Shift Ins (INS) | VAF 51/185 reads (28%) | called by mutect2, pindel, varscan2
- CPNE2 | c.1626del p.T543Pfs*121 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- CRTC1 | c.1813del p.L605* | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | called by mutect2, varscan2
- DARS2 | c.1090dup p.H364Pfs*11 | Frame Shift Ins (INS) | VAF 51/176 reads (29%) | called by mutect2, pindel, varscan2
- EIF3J | c.180del p.E61Rfs*5 | Frame Shift Del (DEL) | VAF 64/124 reads (52%) | called by mutect2, varscan2
- FAM47A | c.1300dup p.S434Ffs*13 | Frame Shift Ins (INS) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- GDPD4 | c.99del p.F33Lfs*3 | Frame Shift Del (DEL) | VAF 54/150 reads (36%) | called by mutect2, pindel, varscan2
- IFIT3 | c.1173dup p.S392Ifs*3 | Frame Shift Ins (INS) | VAF 19/69 reads (28%) | called by mutect2, pindel, varscan2
- INPP4B | c.278dup p.L93Ffs*9 | Frame Shift Ins (INS) | VAF 42/136 reads (31%) | called by mutect2, pindel, varscan2
- INSYN2A | c.120del p.K40Nfs*49 | Frame Shift Del (DEL) | VAF 32/112 reads (29%) | called by mutect2, pindel, varscan2
- ITIH6 | c.2393_2394del p.T798Ifs*5 | Frame Shift Del (DEL) | VAF 58/184 reads (32%) | called by pindel, varscan2
- KDM7A | c.2748del p.G917Efs*15 | Frame Shift Del (DEL) | VAF 50/160 reads (31%) | called by mutect2, pindel, varscan2
- KLF3 | c.677dup p.Q227Afs*37 | Frame Shift Ins (INS) | VAF 36/108 reads (33%) | called by mutect2, varscan2
- LCP2 | c.1360del p.T454Qfs*73 | Frame Shift Del (DEL) | VAF 85/279 reads (30%) | called by mutect2, pindel, varscan2
- MBD6 | c.2012del p.P671Lfs*4 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- MFRP | c.328dup p.N110Kfs*? (on ENST00000449574; = p.N486Kfs*87 on NM_031433.4) | Frame Shift Ins (INS) | VAF 27/94 reads (29%) | called by mutect2, pindel, varscan2
- NIN | c.1304del p.N435Mfs*19 | Frame Shift Del (DEL) | VAF 75/218 reads (34%) | called by mutect2, pindel, varscan2
- NMT1 | c.625del p.Q209Sfs*35 | Frame Shift Del (DEL) | VAF 31/91 reads (34%) | called by mutect2, pindel, varscan2
- NSD3 | c.939del p.F313Lfs*67 | Frame Shift Del (DEL) | VAF 71/178 reads (40%) | called by mutect2, pindel, varscan2
- PCDHB4 | c.906dup p.K303Efs*10 | Frame Shift Ins (INS) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- PIK3C2B | c.859del p.R287Afs*92 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- PLEC | c.690del p.R231Gfs*22 (on ENST00000322810 / NM_201380.4; = p.R121Gfs*22 on NM_000445.5) | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- RBM27 | c.2644del p.T882Hfs*11 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | called by mutect2, pindel, varscan2
- RMND5A | c.890_893del p.I297Tfs*5 | Frame Shift Del (DEL) | VAF 52/146 reads (36%) | called by pindel, varscan2
- SBNO1 | c.2372del p.K791Rfs*5 (on ENST00000420886; = p.K790Rfs*5 on NM_018183.5) | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | called by mutect2, varscan2
- SLC38A3 | c.84del p.M29Wfs*75 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, varscan2
- TNS1 | c.1179del p.N394Tfs*9 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | called by mutect2, pindel, varscan2
- TTN | c.10552del p.D3518Mfs*7 (on ENST00000591111; = p.D3472Mfs*7 on NM_003319.4) | Frame Shift Del (DEL) | VAF 36/111 reads (32%) | called by mutect2, pindel, varscan2
- ULBP2 | c.196T>C p.C66R | Missense Mutation (SNP) | VAF 41/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDFY3 | c.8913dup p.P2972Tfs*27 | Frame Shift Ins (INS) | VAF 48/148 reads (32%) | called by mutect2, pindel, varscan2
- WWC2 | c.616del p.M206Cfs*17 | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | called by mutect2, varscan2
- ZMIZ1 | c.2774del p.P925Rfs*82 | Frame Shift Del (DEL) | VAF 30/64 reads (47%) | called by mutect2, pindel, varscan2
- ZNF23 | c.366del p.F122Lfs*35 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | called by mutect2, pindel, varscan2
- ZNF652 | c.1619dup p.R541Sfs*38 | Frame Shift Ins (INS) | VAF 82/285 reads (29%) | called by mutect2, pindel, varscan2
- AASDH | c.2565T>C p.A855= | Silent (SNP) | VAF 86/252 reads (34%) | catalogued as COSV52707707; called by muse, mutect2, varscan2
- ADAMTS20 | c.255C>T p.Y85= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs754458406, COSV67125847; called by muse, mutect2, varscan2
- ADGRL2 | c.3177T>C p.N1059= (on ENST00000370717 / NM_001366005.1; = p.N1046= on NM_012302.4) | Silent (SNP) | VAF 29/299 reads (10%) | catalogued as COSV54673196; called by muse, mutect2, varscan2
- ADGRL3 | c.1569C>T p.T523= (on ENST00000506720 / NM_001322402.2; = p.T455= on NM_015236.6) | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as COSV72230963; called by muse, mutect2, varscan2
- AKAP11 | c.1731C>A p.T577= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV50297867; called by muse, mutect2, varscan2
- ALMS1 | c.5538G>A p.L1846= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV52512843; called by muse, mutect2, varscan2
- ANKRD12 | c.444C>T p.N148= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs1420660506, COSV50830214; called by muse, mutect2
- ARHGDIA | c.477G>C p.L159= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs780341101, COSV53907149; called by muse, mutect2, varscan2
- ARMC2 | c.795C>T p.D265= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs775569588, COSV64551672; called by muse, mutect2, varscan2
- ATRNL1 | c.1134T>C p.D378= | Silent (SNP) | VAF 53/123 reads (43%) | catalogued as COSV61807277; called by muse, mutect2, varscan2
- C19orf47 | c.567G>A p.R189= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV100775109, COSV63509646; called by muse, mutect2
- C5orf34 | c.1107T>C p.F369= | Silent (SNP) | VAF 54/151 reads (36%) | catalogued as COSV60930735; called by muse, mutect2, varscan2
- CACNA1G | c.4185G>A p.A1395= | Silent (SNP) | VAF 68/161 reads (42%) | catalogued as rs759239505, COSV61730741; called by muse, mutect2, varscan2
- CBFB | c.249A>T p.R83= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV51998953, COSV51999205; called by muse, mutect2, varscan2
- CCDC126 | c.90G>A p.L30= | Silent (SNP) | VAF 78/188 reads (41%) | catalogued as COSV56740339; called by muse, mutect2, varscan2
- CCDC40 | c.399C>T p.S133= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs371207249, COSV53900719; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDON | c.1821C>T p.P607= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV54999258; called by muse, mutect2, varscan2
- CEBPZ | c.723G>A p.S241= | Silent (SNP) | VAF 53/117 reads (45%) | catalogued as rs1055340783, COSV50017929; called by muse, mutect2, varscan2
- CELA2A | c.498C>T p.N166= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs376252962; called by muse, mutect2, varscan2
- CELSR2 | c.3759G>A p.A1253= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV54774279, COSV54774357; called by muse, mutect2, varscan2
- CLEC16A | c.984G>A p.P328= | Silent (SNP) | VAF 107/258 reads (41%) | catalogued as rs192627479; called by muse, mutect2, varscan2
- CLIP1 | c.4152C>T p.C1384= (on ENST00000620786 / NM_001247997.1; = p.C1373= on NM_002956.2) | Silent (SNP) | VAF 63/161 reads (39%) | catalogued as COSV56803562; called by muse, mutect2, varscan2
- CLU | c.510G>A p.T170= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs534508746, COSV57066604; called by muse, mutect2, varscan2
- CLUH | c.1611C>T p.N537= (on ENST00000435359; = p.N575= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs749033352, COSV70929198; called by muse, mutect2, varscan2
- COL11A1 | c.828A>C p.A276= | Silent (SNP) | VAF 81/295 reads (27%) | catalogued as COSV62186977; called by muse, mutect2, varscan2
- CPT2 | c.1827C>T p.G609= | Silent (SNP) | VAF 65/152 reads (43%) | catalogued as COSV53759621; called by muse, mutect2, varscan2
- CRYBG1 | c.6204G>A p.L2068= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV64812818; called by muse, mutect2, varscan2
- CUBN | c.909C>T p.C303= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as rs543709109, COSV64707159; called by muse, mutect2, varscan2
- DCAF1 | c.2701C>A p.R901= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as COSV60040549, COSV60044106; called by muse, mutect2, varscan2
- DCBLD1 | c.1128G>A p.R376= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV51642458; called by muse, mutect2, varscan2
- DNAH11 | c.6441G>A p.L2147= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV60962203; called by muse, mutect2, varscan2
- DNAH3 | c.5886C>T p.T1962= | Silent (SNP) | VAF 14/208 reads (7%) | catalogued as rs566185936, COSV54502330, COSV99771263; called by muse, mutect2
- ECPAS | c.4725G>A p.T1575= | Silent (SNP) | VAF 44/127 reads (35%) | catalogued as rs372133962, COSV52200328; called by muse, mutect2, varscan2
- EP400 | c.8232G>A p.Q2744= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs768680596; called by muse, varscan2
- FOXP2 | c.522A>G p.Q174= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs368614280; ClinVar: benign; called by muse, mutect2
- FRMPD4 | c.126G>A p.T42= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs138984910, COSV66217154; called by muse, mutect2, varscan2
- GABRD | c.699G>A p.Q233= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV66081003; called by muse, mutect2
- GAMT | c.378C>T p.D126= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs538244028, COSV52039753; called by muse, mutect2, varscan2
- GIMAP8 | c.1638G>A p.A546= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs897850406, COSV56231089; called by muse, mutect2, varscan2
- GJA10 | c.57C>A p.T19= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV65355426; called by muse, mutect2, varscan2
- GLS2 | c.1669C>T p.L557= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV57665664; called by muse, mutect2, varscan2
- GPR137 | c.537C>T p.S179= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs371290655; called by muse, mutect2, varscan2
- GPR84 | c.525C>T p.G175= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV57209940; called by muse, mutect2, varscan2
- IGHV1-2 | c.123C>T p.C41= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as rs782418030; called by muse, mutect2, varscan2
- IMMP2L | c.498G>A p.E166= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV100072708, COSV59246301; called by muse, mutect2, varscan2
- ITPKC | c.1881C>T p.D627= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV54575554; called by muse, mutect2, varscan2
- KCNU1 | c.2733C>T p.A911= | Silent (SNP) | VAF 71/151 reads (47%) | catalogued as COSV67757203; called by muse, mutect2, varscan2
- KIF21B | c.1182G>A p.R394= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as COSV59760001; called by muse, mutect2, varscan2
- KLHL13 | c.1746C>T p.V582= | Silent (SNP) | VAF 100/269 reads (37%) | catalogued as rs373625143, COSV53249360; called by muse, mutect2, varscan2
- KPRP | c.861C>A p.P287= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV64222026; called by muse, mutect2, varscan2
- LRP1 | c.7254G>A p.E2418= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV54515631; called by muse, mutect2
- LRRC4B | c.678G>A p.T226= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs745383249, COSV65350279; called by muse, mutect2, varscan2
- LRRK2 | c.2067A>G p.Q689= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as rs1267546932, COSV54152268; called by muse, mutect2
- MYO15A | c.10518C>T p.A3506= | Silent (SNP) | VAF 27/166 reads (16%) | catalogued as rs750017337, COSV52759220; called by muse, mutect2, varscan2
- NACC2 | c.906A>G p.P302= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV53201168; called by muse, mutect2, varscan2
- NFASC | c.2955T>C p.A985= | Silent (SNP) | VAF 144/361 reads (40%) | catalogued as rs1465714981, COSV58369036; called by muse, mutect2, varscan2
- NIPBL | c.1464G>A p.R488= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs979685506, COSV56955691; called by muse, mutect2, varscan2
- NME1-NME2 | c.666C>T p.N222= (on ENST00000555572; = p.N197= on NM_001018136.3) | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as rs754370128, COSV64510571; called by muse, mutect2
- ODF1 | c.129C>A p.P43= | Silent (SNP) | VAF 67/180 reads (37%) | catalogued as COSV53432950; called by muse, mutect2, varscan2
- OR1M1 | c.537C>T p.C179= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs923946328, COSV70037048; called by muse, mutect2, varscan2
- OR2AG2 | c.30C>T p.S10= | Silent (SNP) | VAF 58/130 reads (45%) | catalogued as rs750534649, COSV58454887; called by muse, mutect2, varscan2
- ORMDL3 | c.18G>A p.A6= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs566704888, COSV58345954; called by muse, mutect2, varscan2
- PCDHA5 | c.2001G>A p.S667= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1013042375, COSV65350967; called by muse, mutect2
- PCDHB5 | c.1527C>T p.N509= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs377744960; called by muse, mutect2, varscan2
- PCDHGA5 | c.1677G>A p.T559= | Silent (SNP) | VAF 55/107 reads (51%) | catalogued as rs764457320, COSV53944256; called by muse, mutect2, varscan2
- PFKFB2 | c.996T>C p.C332= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs1370905844, COSV65548592; called by muse, mutect2, varscan2
- PTPRS | c.5031C>T p.V1677= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs762962610, COSV53624269; called by muse, mutect2
- RBBP4 | c.33A>G p.A11= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV59385838; called by muse, mutect2, varscan2
- RBM15B | c.1380C>T p.Y460= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs1559455380, COSV60371022; called by muse, mutect2, varscan2
- RBM22 | c.1017T>A p.P339= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV52271958; called by muse, mutect2
- RFWD3 | c.762T>C p.C254= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as COSV63098072; called by muse, mutect2, varscan2
- RIF1 | c.744C>T p.Y248= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as rs767405116, COSV54618923; called by muse, mutect2, varscan2
- RPGR | c.2919G>A p.P973= (on ENST00000339363 / NM_001367249.1; = p.P768= on NM_000328.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 88/242 reads (36%) | catalogued as rs781426804, COSV58832375; called by muse, mutect2, varscan2
- RPS2 | c.759C>T p.P253= | Silent (SNP) | VAF 52/147 reads (35%) | catalogued as rs145826103, COSV51909875; called by muse, mutect2, varscan2
- SH3RF1 | c.351C>T p.G117= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs1340451028, COSV52921851; called by muse, mutect2, varscan2
- SLC43A2 | c.861G>A p.A287= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs768378093, COSV56769699; called by muse, mutect2, varscan2
- SLIT3 | c.4440G>T p.G1480= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV60615580; called by muse, mutect2, varscan2
- SPAG16 | c.1842C>T p.D614= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as rs765928542, COSV56967112; called by muse, mutect2, varscan2
- SPEF2 | c.3774G>A p.Q1258= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as COSV61549470; called by muse, mutect2, varscan2
- SRGAP1 | c.3150G>A p.L1050= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV61899496; called by muse, mutect2, varscan2
- SRPK1 | c.1572C>A p.I524= | Silent (SNP) | VAF 97/242 reads (40%) | catalogued as COSV60413754; called by muse, mutect2, varscan2
- SUV39H1 | c.69C>T p.C23= | Silent (SNP) | VAF 57/122 reads (47%) | catalogued as COSV61920922; called by muse, mutect2, varscan2
- TBC1D2 | c.2157G>A p.A719= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs564134713, COSV59785853; called by muse, mutect2, varscan2
- TIFA | c.474G>A p.R158= | Silent (SNP) | VAF 60/152 reads (39%) | catalogued as COSV64631894; called by muse, mutect2
- TPH2 | c.954T>C p.H318= | Silent (SNP) | VAF 59/163 reads (36%) | catalogued as COSV61592627; called by muse, mutect2, varscan2
- TRERF1 | c.198C>T p.G66= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV61673646; called by muse, mutect2, varscan2
- TRPM6 | c.2250C>T p.S750= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as COSV62514302; called by muse, mutect2, varscan2
- TTI1 | c.3099C>T p.H1033= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV65062015; called by muse, mutect2, varscan2
- TTN | c.17607G>A p.T5869= (on ENST00000591111; = p.T4942= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs778145097, COSV100621706, COSV59865395; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBE3C | c.3000G>T p.V1000= | Silent (SNP) | VAF 53/147 reads (36%) | catalogued as COSV61954036; called by muse, mutect2, varscan2
- UBE3D | c.834A>G p.K278= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV52754674; called by muse, mutect2, varscan2
- ULK1 | c.288C>T p.N96= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs371409689; called by muse, mutect2, varscan2
- VPS41 | c.975A>G p.R325= | Silent (SNP) | VAF 60/135 reads (44%) | catalogued as COSV59649927; called by muse, mutect2, varscan2
- ZNF317 | c.621G>A p.P207= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs145788166; called by muse, mutect2, varscan2
- ZNF646 | c.2922G>A p.E974= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV54925063; called by muse, mutect2, varscan2
- ZNF804A | c.2595C>T p.I865= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs1482520139, COSV56443093, COSV56450055; called by muse, mutect2, varscan2
- ZNF808 | c.2382G>A p.T794= | Silent (SNP) | VAF 63/154 reads (41%) | catalogued as rs765249555, COSV63118661; called by muse, mutect2, varscan2
- ZZEF1 | c.2946G>A p.T982= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs773707140, COSV67558314; called by muse, mutect2, varscan2
- ANKRD13D | c.*1281C>T | 3'UTR (SNP) | VAF 33/95 reads (35%) | catalogued as COSV57385284; called by muse, mutect2, varscan2
- BTN2A3P | n.1119T>C | RNA (SNP) | VAF 84/196 reads (43%) | catalogued as rs1314772785; called by muse, mutect2, varscan2
- EI24P4 | n.1055G>A | RNA (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- MIR100 | n.44C>A | RNA (SNP) | VAF 51/159 reads (32%) | called by muse, mutect2, varscan2
- RASA1 | c.539+59T>C | Intron (SNP) | VAF 69/188 reads (37%) | catalogued as COSV57197282; called by muse, mutect2, varscan2
- SSPOP | n.8973T>C | RNA (SNP) | VAF 10/34 reads (29%) | catalogued as COSV65131976; called by muse, mutect2, varscan2
